FM case AD599 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Specialized Gonadal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/812282d1-d17e-4bd3-8b52-ec60fa7b3e1e

Female, 54.4 years: Granulosa cell tumor, NOS (ICD-O-3 8620/1) of the ovary. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
